Somatic mutation profile of tumor specimen TARGET-10-PAPAGV-09A (aliquot TARGET-10-PAPAGV-09A-01D) from TARGET case TARGET-10-PAPAGV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,104 days).
Specimen TARGET-10-PAPAGV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae54d8a6-04b6-4f55-8319-44809b5ced76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPAGV-10A (Blood Derived Normal), aliquot TARGET-10-PAPAGV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e82f009a-cf76-4813-aa16-7f10993b91e1

The open-access MAF lists 150 somatic variants for this specimen: 100 protein-altering or splice-affecting, 19 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 19, Intron 17, Nonsense Mutation 8, RNA 5, 5'Flank 4, 3'UTR 3, 5'UTR 2, Frame Shift Ins 2, Splice Region 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAF1 | c.1837C>G p.L613V | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as rs80338797, CM073302, COSV50103946; ClinVar: pathogenic; called by muse, mutect2
- ANKRD30B | c.3366G>C p.K1122N | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV57701874; called by muse, mutect2, varscan2
- ATP11B | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.362); catalogued as rs761176675, COSV60030857; called by muse, mutect2, varscan2
- BRWD3 | c.2515G>T p.D839Y | Missense Mutation (SNP) | VAF 83/263 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV64749885; called by muse, mutect2, varscan2
- CAPN6 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.407); catalogued as COSV60695893; called by muse, mutect2
- CHSY3 | c.1822C>T p.Q608* | Nonsense Mutation (SNP) | VAF 24/154 reads (16%) | catalogued as rs746694417; called by muse, mutect2, varscan2
- CTNNA1 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as rs1335925565; called by muse, mutect2
- DHX32 | c.1174C>A p.L392I | Missense Mutation (SNP) | VAF 8/185 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as COSV52938822; called by muse, mutect2
- ERICH6 | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99901450; called by muse, mutect2, varscan2
- FAM135B | c.3270G>C p.E1090D | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs1209878478; called by muse, mutect2, varscan2
- FHL1 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs367592190; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- FMO4 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.174); catalogued as COSV100882041, COSV63000984; called by muse, mutect2, varscan2
- FREM2 | c.2079C>G p.I693M | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV54835012; called by muse, mutect2
- GREB1L | c.4337G>A p.R1446H | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1383051844; called by muse, mutect2, varscan2
- KMT2C | c.1767G>C p.K589N | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV51427709; called by muse, mutect2
- MBD5 | c.1867A>G p.M623V | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1335159571; called by muse, mutect2, varscan2
- MOSPD1 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs1250937408; called by muse, mutect2, varscan2
- NOL8 | c.3190G>A p.E1064K | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs549175396; called by muse, mutect2
- NPC1L1 | c.2737G>A p.E913K | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.9); PolyPhen benign (0.014); catalogued as rs756628304, COSV56923389; called by muse, mutect2, varscan2
- OR2L13 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766931382, COSV63556734; called by muse, mutect2, varscan2
- OR52E4 | c.279G>C p.E93D | Missense Mutation (SNP) | VAF 43/205 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as rs769888166, COSV57625394; called by muse, mutect2, varscan2
- PCDH19 | c.2485G>A p.E829K (on ENST00000373034 / NM_001184880.2; = p.E782K on NM_020766.3) | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV55263355; called by muse, mutect2, varscan2
- PIGH | c.151G>C p.A51P | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.085); catalogued as COSV99373063; called by muse, varscan2
- PKD2L2 | c.389G>C p.R130T | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99296557; called by muse, mutect2, varscan2
- PPP1R26 | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV63356158; called by muse, mutect2, varscan2
- PRKDC | c.7468G>A p.E2490K | Missense Mutation (SNP) | VAF 25/222 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV58049434; called by muse, mutect2, varscan2
- RAD51AP2 | c.2630C>G p.S877* | Nonsense Mutation (SNP) | VAF 6/100 reads (6%) | catalogued as COSV101208282, COSV104433749; called by muse, mutect2
- SCP2D1 | c.454G>C p.D152H | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV53856733, COSV53857824; called by muse, mutect2, varscan2
- SLX4 | c.5228C>T p.S1743L | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs144057906, COSV99567897; called by muse, mutect2, varscan2
- TAB2 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 16/420 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.166); catalogued as rs1385042969; called by muse, mutect2
- TCEAL3 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 15/371 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.227); catalogued as COSV54580771; called by muse, mutect2
- TEX264 | c.268G>C p.D90H | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV100392679; called by muse, mutect2, varscan2
- UBR5 | c.1777G>T p.E593* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV55294032; called by muse, mutect2, varscan2
- UPF2 | c.385C>G p.Q129E | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.68); catalogued as rs1198984259; called by muse, mutect2, varscan2
- VPS13B | c.6640C>G p.L2214V | Missense Mutation (SNP) | VAF 23/222 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV100661965; called by muse, mutect2
- ZBTB49 | c.1582C>T p.R528W | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs774822172, COSV61924427; called by muse, mutect2, varscan2
- ZC3H7B | c.2675G>T p.C892F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60963651; called by muse, mutect2, varscan2
- ZNF677 | c.7C>G p.L3V | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as rs771099483, COSV61721569; called by muse, mutect2, varscan2
- ZSCAN5B | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs1244662861, COSV62839744; called by muse, mutect2
- ADAMTS20 | c.5672G>A p.G1891E | Missense Mutation (SNP) | VAF 44/239 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF38 | c.388G>C p.D130H | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- ASCC3 | c.4294G>A p.D1432N | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP8A1 | c.2356G>C p.E786Q | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.142); called by muse, mutect2
- BHMT | c.838G>C p.D280H | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CCBE1 | c.1194G>C p.L398F | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP104 | c.1395G>A p.M465I | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- CMSS1 | c.441G>T p.R147S | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.033); called by muse, mutect2
- COL24A1 | c.1184C>G p.S395C | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CREBRF | c.528G>C p.K176N | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2
- DNAH7 | c.9028C>G p.L3010V | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); called by muse, varscan2
- DYSF | c.5129G>C p.R1710T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- EDC4 | c.3136G>A p.E1046K | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ETV2 | c.635C>A p.S212* | Nonsense Mutation (SNP) | VAF 6/138 reads (4%) | called by muse, mutect2
- FAU | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- FGF14 | c.127C>T p.L43F | Missense Mutation (SNP) | VAF 8/171 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- FRY | c.6163G>A p.D2055N | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GAS2 | c.13C>G p.L5V | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GPR180 | c.742G>C p.D248H | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GPRASP2 | c.617C>G p.S206C | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- H1-7 | c.47G>C p.R16T | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ING3 | c.78_79insACCT p.E27Tfs*2 | Frame Shift Ins (INS) | VAF 28/159 reads (18%) | called by mutect2, pindel*, varscan2
- INTS4 | c.1979C>T p.S660F | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.136); called by muse, mutect2
- KANSL1L | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- KCNMA1 | c.3845G>C p.R1282T | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- KLHL5 | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 22/116 reads (19%) | called by muse, mutect2, varscan2
- LRRC70 | c.695G>A p.R232K | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.019); called by muse, mutect2
- MED17 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- MPST | c.414G>C p.Q138H (on ENST00000341116 / NM_001369904.2; = p.Q158H on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- MRPL33 | c.49C>G p.L17V | Missense Mutation (SNP) | VAF 45/217 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- MUC17 | c.7237G>C p.E2413Q | Missense Mutation (SNP) | VAF 53/391 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- NCBP3 | c.254C>A p.A85E | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR52E4 | c.62G>C p.G21A | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- PCLO | c.4717G>A p.E1573K | Missense Mutation (SNP) | VAF 59/271 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- PDZD2 | c.4147G>T p.D1383Y | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PECR | c.441G>T p.M147I | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHF8 | c.530C>T p.S177L (on ENST00000357988 / NM_001184896.1; = p.S141L on NM_015107.3) | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.034); called by muse, mutect2
- PIK3C3 | c.1027C>G p.Q343E | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- PRKD2 | c.1774G>T p.E592* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2
- PTPRO | c.2165-3C>G | Splice Region (SNP) | VAF 17/104 reads (16%) | called by muse, mutect2, varscan2
- RAPGEF2 | c.1978G>C p.E660Q | Missense Mutation (SNP) | VAF 15/202 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- SETD2 | c.3803_3804dup p.T1269Lfs*64 | Frame Shift Ins (INS) | VAF 59/265 reads (22%) | called by mutect2, pindel, varscan2
- SHROOM4 | c.4087G>C p.E1363Q | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SLC30A6 | c.1309C>T p.Q437* | Nonsense Mutation (SNP) | VAF 33/205 reads (16%) | called by muse, mutect2, varscan2
- SLC9A7 | c.751G>C p.D251H | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- SNAPC1 | c.15_34del p.L7Afs*74 | Frame Shift Del (DEL) | VAF 15/89 reads (17%) | called by mutect2, pindel, varscan2
- TDRKH | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- TEX14 | c.2002G>C p.E668Q (on ENST00000240361 / NM_001201457.2; = p.E662Q on NM_031272.5) | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- TLE4 | c.1007G>A p.G336D | Missense Mutation (SNP) | VAF 13/229 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2
- TRIM49 | c.940G>C p.D314H | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- UBR3 | c.5288G>A p.R1763K | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.931); called by muse, mutect2
- VARS2 | c.2518C>G p.Q840E | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.115); called by muse, mutect2
- VAT1L | c.1048G>A p.V350M | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- VCL | c.509A>C p.K170T | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- WTIP | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2
- ZGRF1 | c.910G>C p.E304Q | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- ZNF266 | c.18G>C p.K6N | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF276 | c.556+3G>T | Splice Region (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- ZNF77 | c.616C>G p.L206V | Missense Mutation (SNP) | VAF 11/224 reads (5%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.528); called by muse, mutect2
- ZNF852 | c.20C>T p.T7I | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNHIT2 | c.257T>G p.L86R | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- CYP4A22 | c.79C>T p.L27= | Silent (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- EPN1 | c.771C>G p.L257= (on ENST00000270460 / NM_001321263.1; = p.L232= on NM_013333.3) | Silent (SNP) | VAF 14/116 reads (12%) | called by muse, mutect2, varscan2
- FAT3 | c.8007G>C p.L2669= | Silent (SNP) | VAF 50/199 reads (25%) | catalogued as COSV53104038, COSV53147183; called by muse, mutect2, varscan2
- FRMPD3 | c.3984G>A p.Q1328= | Silent (SNP) | VAF 22/99 reads (22%) | called by muse, mutect2, varscan2
- MCM7 | c.1827C>T p.I609= | Silent (SNP) | VAF 8/156 reads (5%) | called by muse, mutect2
- MRPL49 | c.402G>A p.K134= | Silent (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2
- NEMP1 | c.420C>G p.L140= | Silent (SNP) | VAF 30/169 reads (18%) | catalogued as COSV55663640; called by muse, mutect2, varscan2
- NUTF2 | c.303G>A p.Q101= | Silent (SNP) | VAF 25/73 reads (34%) | called by muse, mutect2, varscan2
- PLD5 | c.241C>T p.L81= (on ENST00000442594; = p.L19= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/277 reads (3%) | called by muse, mutect2
- RGS7 | c.1230C>T p.N410= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV58535609; called by muse, mutect2, varscan2
- SCN9A | c.993G>C p.V331= | Silent (SNP) | VAF 12/168 reads (7%) | called by muse, mutect2
- SIX1 | c.483C>T p.T161= | Silent (SNP) | VAF 35/139 reads (25%) | catalogued as rs758128766, COSV55959863; called by muse, mutect2, varscan2
- SNAPC1 | c.1106G>A p.*369= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as rs1190096774; called by muse, mutect2, varscan2
- SUPT20HL2 | c.78G>A p.R26= | Silent (SNP) | VAF 10/308 reads (3%) | called by muse, mutect2
- SYVN1 | c.1413C>T p.F471= (on ENST00000377190 / NM_172230.3; = p.F470= on NM_032431.3) | Silent (SNP) | VAF 17/85 reads (20%) | called by muse, mutect2, varscan2
- SYVN1 | c.162C>T p.V54= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as rs1342430360, COSV53697517; called by muse, mutect2, varscan2
- TG | c.6744C>T p.P2248= | Silent (SNP) | VAF 4/74 reads (5%) | called by muse, mutect2
- TTC21B | c.1032G>A p.L344= | Silent (SNP) | VAF 31/143 reads (22%) | catalogued as rs958096201; called by muse, mutect2, varscan2
- TTC8 | c.1161C>T p.F387= (on ENST00000338104 / NM_001288781.1; = p.F371= on NM_144596.4) | Silent (SNP) | VAF 20/108 reads (19%) | called by muse, mutect2, varscan2
- AC020637.1 | n.610G>A | RNA (SNP) | VAF 9/50 reads (18%) | catalogued as rs1340792289; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73845804 G>A | 5'Flank (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848895 G>C | 5'Flank (SNP) | VAF 61/273 reads (22%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849992 C>A | 5'Flank (SNP) | VAF 19/119 reads (16%) | called by muse, mutect2, varscan2
- ANK3 | c.12596-97G>C | Intron (SNP) | VAF 22/112 reads (20%) | called by muse, mutect2, varscan2
- ANKMY1 | c.904-10C>G | Intron (SNP) | VAF 15/101 reads (15%) | called by muse, mutect2, varscan2
- CFAP298 | c.762+115C>G | Intron (SNP) | VAF 17/59 reads (29%) | called by muse, mutect2, varscan2
- CFAP298 | c.762+24C>G | Intron (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- CWF19L1 | c.505-44G>C | Intron (SNP) | VAF 14/119 reads (12%) | catalogued as rs1307046384; called by muse, mutect2, varscan2
- DNAH11 | c.12934-38G>T | Intron (SNP) | VAF 15/159 reads (9%) | called by muse, mutect2
- DYNC1I1 | c.-9-406C>G | Intron (SNP) | VAF 51/235 reads (22%) | called by muse, mutect2, varscan2
- EFL1P1 | n.1169G>A | RNA (SNP) | VAF 8/238 reads (3%) | called by muse, mutect2
- EHF | c.343+108C>A | Intron (SNP) | VAF 19/58 reads (33%) | called by muse, mutect2, varscan2
- ENTPD3 | c.168+75G>C | Intron (SNP) | VAF 22/136 reads (16%) | called by muse, mutect2, varscan2
- EYS | c.8072-2856C>A | Intron (SNP) | VAF 16/47 reads (34%) | catalogued as COSV65473979; called by muse, mutect2, varscan2
- FBLN1 | chr22:45502254 G>T | 5'Flank (SNP) | VAF 9/271 reads (3%) | called by muse, mutect2
- LRP2 | c.-22G>A | 5'UTR (SNP) | VAF 23/70 reads (33%) | called by muse, mutect2, varscan2
- MSH5 | c.1014+97C>G | Intron (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2
- NDUFS2 | c.866+71C>G | Intron (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- NEMP1 | c.*95G>A | 3'UTR (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- OR4C49P | n.393G>C | RNA (SNP) | VAF 34/113 reads (30%) | called by muse, mutect2, varscan2
- OXR1 | c.1960-11429C>G | Intron (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2
- RALYL | c.-24+714C>T | Intron (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2, varscan2
- RTL3 | c.*45C>G | 3'UTR (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2
- SRL | c.62-2313G>C | Intron (SNP) | VAF 47/147 reads (32%) | called by muse, mutect2, varscan2
- TPM4 | c.*201G>C | 3'UTR (SNP) | VAF 9/69 reads (13%) | called by muse, varscan2
- TRGV2 | c.-20A>C | 5'UTR (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2
- TTC23L | c.949+127C>T | Intron (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- UBTFL2 | n.200C>T | RNA (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- XIST | n.10139C>T | RNA (SNP) | VAF 57/357 reads (16%) | called by muse, mutect2, varscan2
- ZNF77 | c.4-74C>T | Intron (SNP) | VAF 8/174 reads (5%) | called by muse, mutect2
